Gene-level copy-number profile of tumor specimen TCGA-06-0149-01A from TCGA case TCGA-06-0149, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.8 years (27,315 days).
Specimen TCGA-06-0149-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.2ab0f8fe-bbc6-4f02-9eec-95a9d57c3f99.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,998 have no estimate.
https://portal.gdc.cancer.gov/files/64346219-9d89-4ad1-9881-0d1d78820bee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,723; copy number 2: 45,804; copy number 3: 2,049; copy number 4: 2,985; copy number 11: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-0149-01): tumor purity 0.73, ploidy 2.06, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,751,512–87,863,533, 4 genes: ATAD1, CFL1P1, RN7SL78P, KLLN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 60 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,494,153–205,457,091, 60 genes, copy number 11: OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1.

Autosomal genes at a single copy (total copy number 1): 4,723. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
